Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29X, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29X-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Conies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Melanoma recurrence (L) upper neck. (Previous neck dissection).

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrar: Pathologist:

MACROSCOPIC DESCRIPTION

(Dr

"LEFT UPPER NECK TUMOUR". Consists of a fibrofatty piece of tissue, 40mm x 25mm x 13mm. No skin surface is identified. A 10mm black nodule is seen ?involved lymph node.

1A. The dark black nodule bisected.

1B. Two possible lymph nodes

MICROSCOPIC REPORT

"LEFT UPPER NECK TUMOUR". The residual part of an enlarged lymph node (1A) is largely replaced by heavily pigmented epithelioid cell melanoma. No extranodal spread seen in the residuum. Two small lymph nodes (1A, 1B) show no evidence of malignancy.

SUMMARY

Lymph node, left upper neck - Metastatic melanoma.

REPORTED BY: Prof

1CD-0-3

Melanoma, NOS 8720/3

Sites Subcutaneous tissue, neck
C49.0

hw
6/2/11

Case is (clinc):		
hw 6/2/11		

A Unit of

Prir

This fax was received by

For more information, visit

Source: NCI Genomic Data Commons file e5f37205-8ddc-4a06-8f52-d472751061c9 (TCGA-EE-A29X.26C1B87F-9E43-4D68-9F89-6831FCAA1044.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).